Gene-level copy-number profile of tumor specimen TCGA-EE-A3J3-06A from TCGA case TCGA-EE-A3J3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.4 years (20,585 days).
Specimen TCGA-EE-A3J3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c67ec202-ace7-4003-b24e-3cc25e64e531.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A3J3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6cdcd66-9347-4cca-bd5b-52313cf171b5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 853; copy number 2: 7,536; copy number 3: 17,088; copy number 4: 19,337; copy number 5: 8,846; copy number 6: 5,704; copy number 7: 392.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A3J3-06A-11D-A20B-01): tumor purity 0.63, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,965,227, 4 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr10:63,110,139–63,155,031, 3 genes: RNU6-543P, AL590502.1, NRBF2.
- chr10:63,222,155–63,223,045, 1 gene: TATDN1P1.
- chr15:30,355,436–32,173,018, 50 genes (within-gene range 0–1): Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P, AC091057.3, AC091057.2, ARHGAP11B, AC091057.5, AC091057.6, AC091057.1, Y_RNA, AC091057.4, GOLGA8UP, RN7SL82P, HERC2P10, AC087481.1, FAN1, AC087481.2, MTMR10, RNU6-466P, AC009562.1, TRPM1, MIR211, LINC02352, AC012236.1, KLF13, UBE2CP4, AC104759.1, OTUD7A, DEPDC1P1, AC026951.1, CHRNA7, AC079969.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 853. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
